CPTAC case C3L-01954 — Kidney — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Kidney. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/7025c69a-f585-42be-9442-05ecc9f64985

Demographics
Sex at birth: female; Race: white; Year of birth: 1949; Vital status: Alive.

Diagnoses (1)
1. Renal cell carcinoma, NOS: ICD-O-3 morphology code: 8312/3; Tissue or organ of origin: Kidney, NOS; Site of resection or biopsy: Kidney, NOS; Age at diagnosis: 67.7 years (24,719 days); Year of diagnosis: 2017; AJCC staging edition: 7th; AJCC clinical M: MX; AJCC pathologic T: T1b; AJCC pathologic N: NX; AJCC pathologic M: MX; AJCC pathologic stage: Stage I; Tumor grade: G3; Residual disease: RX; Days to last known disease status: 55 days; Days to last follow up: 55 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 4.4 cm (a second GDC size field records 3.5 cm); Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 0; Margin status: Uninvolved; Sarcomatoid present: No.

Follow-up (1 entry)
- Days to follow up: 55 days; Karnofsky performance status: 100.

Other clinical attributes
- Weight: 137.44 kg; Height: 162.56 cm; BMI: 52; Diabetes treatment type: Insulin.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Reformed Smoker for > 15 yrs; Pack years smoked: 9; Cigarettes per day: 10; Tobacco smoking onset year: 1969; Tobacco smoking quit year: 1987; Exposure duration years: 18.

Biospecimens (4 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-01954-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Biospecimen laterality: Left; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: 0 days; Initial weight: 210 mg; Time between excision and freezing: 13 minutes; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-01954-21: Section location: Lower pole; Percent tumor nuclei: 80; Percent necrosis: 5.
- Sample C3L-01954-02: Sample type: Solid Tissue Normal; Tissue type: Normal; Specimen type: Solid Tissue; Preservation method: Snap Frozen; Freezing method: LN2; Initial weight: 100 mg.
- Sample C3L-01954-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: 0 days; Method of sample procurement: Blood Draw.
- Sample C3L-01954-32: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC).
